Somatic mutation profile of tumor specimen TCGA-AY-A8YK-01A (aliquot TCGA-AY-A8YK-01A-11D-A40P-10) from TCGA case TCGA-AY-A8YK, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 44.2 years (16,140 days).
Specimen TCGA-AY-A8YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68f83fcb-a081-41e7-8be3-d276e295e3d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-A8YK-10A (Blood Derived Normal), aliquot TCGA-AY-A8YK-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad481027-dd0d-491b-ae64-320dfc9c4b66

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Nonsense Mutation 5, RNA 2, 3'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.532-2A>G p.X178_splice | Splice Site (SNP) | VAF 56/278 reads (20%) | catalogued as rs752152148, CS058105, CS102019, CS994296, COSV57334158, COSV99966960; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 87/140 reads (62%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3103C>T p.Q1035* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as CM106362, COSV57349980; called by muse, mutect2, varscan2
- ASXL3 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV52469911; called by muse, mutect2, varscan2
- CCDC61 | c.1289T>A p.F430Y | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.336); catalogued as COSV50516978; called by muse, mutect2, varscan2
- CFTR | c.3367G>T p.G1123* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as CM960289, COSV99135156; called by muse, mutect2, varscan2
- CHRDL1 | c.250C>T p.H84Y (on ENST00000372045; = p.H90Y on NM_145234.4) | Missense Mutation (SNP) | VAF 356/440 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99487944; called by muse, mutect2, varscan2
- CLIP4 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.189); catalogued as rs762644866, COSV100191757; called by muse, mutect2, varscan2
- COL6A2 | c.957G>A p.G319= | Splice Region (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100153290; called by muse, mutect2, varscan2
- CSMD3 | c.9025G>A p.E3009K (on ENST00000297405 / NM_001363185.1; = p.E2840K on NM_052900.3) | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs757229672, COSV52109714; called by muse, mutect2, varscan2
- CUBN | c.8501C>T p.T2834M | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as rs144422027, COSV100912418; called by muse, mutect2, varscan2
- DENND3 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs201075864, COSV99370390; called by muse, mutect2, varscan2
- DOCK1 | c.4276G>C p.V1426L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99728554; called by muse, mutect2, varscan2
- DOCK4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs200422451, COSV101455492; called by muse, mutect2, varscan2
- EXD3 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763757887, COSV59808617; called by muse, mutect2, varscan2
- FKBP11 | c.236C>G p.T79S | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56739755; called by muse, mutect2, varscan2
- GLI3 | c.1841G>T p.C614F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101229803; called by muse, mutect2, varscan2
- GPC6 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 27/173 reads (16%) | catalogued as COSV100988374; called by muse, mutect2, varscan2
- GRID1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs760195348, COSV60025408; called by muse, mutect2, varscan2
- GTF3C1 | c.3039C>G p.N1013K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); catalogued as COSV100649238; called by muse, mutect2, varscan2
- HDAC7 | c.452G>A p.R151H (on ENST00000427332; = p.R190H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50395607; called by muse, mutect2, varscan2
- IFIT2 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99260128; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1439T>G p.L480R | Missense Mutation (SNP) | VAF 86/393 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV100781101; called by muse, mutect2, varscan2
- ITIH1 | c.2005G>A p.V669M | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746112878, COSV56255533; called by muse, mutect2, varscan2
- KCNIP1 | c.132C>A p.C44* (on ENST00000411494 / NM_001034837.3; = p.C33* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV61084944, COSV61086288; called by muse, mutect2, varscan2
- KDM3B | c.4550G>A p.R1517Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100069380; called by muse, mutect2, varscan2
- KPNA2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100388724; called by muse, mutect2, varscan2
- LEPR | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV60757421; called by muse, mutect2, varscan2
- MUC16 | c.1134C>A p.S378R | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs780057979, COSV101199337; called by muse, mutect2
- NCKAP1L | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1212779362, COSV99514851; called by muse, mutect2, varscan2
- NFKB1 | c.939C>A p.F313L (on ENST00000394820 / NM_001382627.1; = p.F314L on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 157/300 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56960960, COSV99896936; called by muse, mutect2, varscan2
- NPB | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs778717259, COSV100325950; called by muse, mutect2, varscan2
- OGDHL | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1331747020, COSV65104090; called by muse, mutect2, varscan2
- OR52N1 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100398635; called by muse, mutect2, varscan2
- P2RY2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1215781979, COSV100232615; called by muse, mutect2, varscan2
- PCDHA13 | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99165600; called by muse, mutect2, varscan2
- PCDHB9 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs1408461979; called by muse, mutect2
- PDE3A | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100762025; called by muse, mutect2, varscan2
- PIAS2 | c.674A>C p.N225T | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV100245180; called by muse, mutect2, varscan2
- POM121C | c.2494G>A p.A832T (on ENST00000607367; = p.A590T on NM_001099415.3) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1161825610; called by mutect2, varscan2
- PRR35 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1404736416, COSV99215939; called by muse, mutect2, varscan2
- RHBDL1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs778588458, COSV99558200; called by muse, mutect2, varscan2
- RPL28 | c.239C>A p.T80N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV59805100; called by muse, mutect2, varscan2
- SCFD2 | c.1553A>T p.K518I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV101189332, COSV66368477; called by muse, mutect2, varscan2
- SLC35A5 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99656745; called by muse, mutect2, varscan2
- SYNE1 | c.16238T>G p.I5413S (on ENST00000367255 / NM_182961.4; = p.I5342S on NM_033071.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99559421; called by muse, mutect2, varscan2
- TAT | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs774152875, COSV100587581; called by muse, mutect2, varscan2
- TBC1D16 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs370476450; called by muse, mutect2, varscan2
- TBX5 | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV100090998; called by muse, mutect2, varscan2
- TEKT1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 59/77 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139532367; called by muse, mutect2, varscan2
- TGFBRAP1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 86/159 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758317376, COSV99304946; called by muse, mutect2, varscan2
- TIAM2 | c.1718G>T p.S573I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100018552, COSV59704969; called by muse, mutect2, varscan2
- TIPARP | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99903753; called by muse, mutect2, varscan2
- TRPM3 | c.3766C>T p.R1256W (on ENST00000357533 / NM_001366142.2; = p.R1111W on NM_020952.6) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs775326354, COSV62585125; called by muse, mutect2
- TTLL7 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs758178107, COSV99552199; called by muse, mutect2, varscan2
- YIPF7 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 72/483 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs1331726179, COSV60657201, COSV60658589; called by muse, mutect2, varscan2
- ZEB2 | c.770A>T p.E257V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100355673; called by muse, varscan2
- ALPI | c.825G>A p.A275= | Silent (SNP) | VAF 87/159 reads (55%) | catalogued as rs766051572, COSV55015531; called by muse, mutect2, varscan2
- CCNB3 | c.744G>A p.S248= | Silent (SNP) | VAF 49/314 reads (16%) | catalogued as rs375491454, COSV99328817; called by muse, mutect2, varscan2
- EPHA6 | c.3085C>A p.R1029= | Silent (SNP) | VAF 48/220 reads (22%) | catalogued as COSV101061750; called by muse, mutect2, varscan2
- HELZ2 | c.3156G>A p.T1052= (on ENST00000467148 / NM_001037335.2; = p.T483= on NM_033405.3) | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs45548036, COSV100915524; called by muse, mutect2, varscan2
- HSPG2 | c.3636C>T p.Y1212= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs775949784, COSV101020590; called by muse, mutect2, varscan2
- JPH1 | c.579C>T p.F193= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV60611729; called by muse, mutect2, varscan2
- KRT25 | c.435C>T p.I145= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs1004816398, COSV56444613; called by muse, mutect2, varscan2
- MBD5 | c.2163G>A p.P721= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs1241365384, COSV101290023, COSV68697047; called by muse, mutect2, varscan2
- MCHR1 | c.606C>T p.I202= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs760177693, COSV50760545; called by muse, mutect2, varscan2
- MYO3A | c.3429T>C p.N1143= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as COSV99779150; called by muse, mutect2
- NFATC2 | c.2535C>T p.G845= | Silent (SNP) | VAF 44/250 reads (18%) | catalogued as COSV101043903; called by muse, mutect2, varscan2
- NRXN1 | c.489C>T p.R163= | Silent (SNP) | VAF 63/154 reads (41%) | catalogued as rs747224688, COSV68017420; called by muse, mutect2, varscan2
- NTRK3 | c.435G>A p.Q145= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV100446286, COSV58124271; called by muse, mutect2, varscan2
- PCDHB9 | c.1503C>A p.A501= | Silent (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2
- PIGK | c.78C>A p.A26= | Silent (SNP) | VAF 37/190 reads (19%) | catalogued as COSV100769830; called by muse, mutect2, varscan2
- PXDNL | c.2493G>A p.P831= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV100681216, COSV62481028; called by muse, mutect2, varscan2
- SPTA1 | c.4032C>A p.T1344= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100934692, COSV63757711; called by muse, mutect2, varscan2
- TRPC7 | c.651G>A p.S217= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs376839341; called by muse, mutect2, varscan2
- ZNF444 | c.786C>T p.R262= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs1217428605, COSV100442561; called by muse, mutect2, varscan2
- AGAP7P | n.1059C>A | RNA (SNP) | VAF 54/311 reads (17%) | called by muse, mutect2, varscan2
- AGAP7P | n.1994C>T | RNA (SNP) | VAF 16/62 reads (26%) | catalogued as rs1383384555; called by mutect2, varscan2
- SLC6A11 | c.*2C>T | 3'UTR (SNP) | VAF 9/50 reads (18%) | catalogued as rs773604512, COSV54394221; called by muse, mutect2, varscan2
